Somatic mutation profile of tumor specimen 0D9T5P from CCDI case PBBIKP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.8 years (2,839 days).
Specimen 0D9T5P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dbc7538-da83-4f6f-9c95-1b520da74d7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9T5R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7460fde9-7424-416b-ae3f-8df35f0bd494

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYBB | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 228/260 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as CP984532; called by muse, varscan2
- DNAH14 | c.7551C>G p.I2517M (on ENST00000445597; = p.I3289M on NM_001367479.1) | Missense Mutation (SNP) | VAF 198/464 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as rs1353892810; called by muse, varscan2
- GNGT2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 192/694 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs1172469007, COSV55929816; called by muse, varscan2
- MET | c.2465T>G p.M822R | Missense Mutation (SNP) | VAF 406/982 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV59260570; called by muse, varscan2
- NEURL3 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 153/341 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.091); catalogued as rs1220334802; called by muse, varscan2
- PRR19 | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 68/556 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56627393; called by muse, varscan2
- RALGAPB | c.3325C>T p.R1109C | Missense Mutation (SNP) | VAF 154/830 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777600119, COSV53446579; called by muse, varscan2
- RGS11 | c.403C>T p.R135W (on ENST00000397770 / NM_183337.3; = p.R114W on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/296 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs150330840; called by muse, varscan2
- SPINT3 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 256/657 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.235); catalogued as rs1176039969; called by muse, varscan2
- SRCAP | c.7549C>A p.Q2517K | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as CD121174; called by muse, varscan2
- TRMT10B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 168/794 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as rs773184391, COSV53051642; called by muse, varscan2
- ADGRF5 | c.589T>A p.Y197N | Missense Mutation (SNP) | VAF 88/542 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ATG9B | c.2299T>C p.F767L | Missense Mutation (SNP) | VAF 302/728 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, varscan2
- EIF2S3B | c.1092A>T p.L364F | Missense Mutation (SNP) | VAF 284/630 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, varscan2
- ERICH6B | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 273/612 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.028); called by muse, varscan2
- HOXB7 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 266/844 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, varscan2
- PCDHB8 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 119/412 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- ROBO1 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 110/768 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, varscan2
- CACNA1G | c.4899C>T p.Y1633= | Silent (SNP) | VAF 242/800 reads (30%) | catalogued as COSV61730872; called by muse, varscan2
- NEB | c.18042C>T p.D6014= | Silent (SNP) | VAF 232/574 reads (40%) | catalogued as rs1267175445; called by muse, varscan2
- PLCXD2 | c.588T>C p.S196= | Silent (SNP) | VAF 153/756 reads (20%) | called by muse, varscan2
- RC3H1 | c.3240A>G p.T1080= | Silent (SNP) | VAF 206/858 reads (24%) | catalogued as rs748463835; called by muse, varscan2
- SPTBN4 | c.435C>A p.I145= | Silent (SNP) | VAF 117/240 reads (49%) | catalogued as rs1176885207, COSV100150148, COSV58948616; called by muse, varscan2
- BCAM | c.204+74C>A | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, varscan2
- CLLU1 | n.1157G>A | RNA (SNP) | VAF 98/242 reads (40%) | catalogued as COSV65903166; called by muse, varscan2
- TP53AIP1 | c.141+231C>T | Intron (SNP) | VAF 13/48 reads (27%) | called by muse, varscan2
- TRAT1 | c.214+82A>G | Intron (SNP) | VAF 14/44 reads (32%) | catalogued as rs1040149569; called by muse, varscan2
